Somatic mutation profile of tumor specimen TARGET-30-PASYTP-01A (aliquot TARGET-30-PASYTP-01A-01D) from TARGET case TARGET-30-PASYTP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.5 years (1,292 days).
Specimen TARGET-30-PASYTP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31b74f4a-1bf2-420a-8cd6-27fed9807853.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASYTP-10A (Blood Derived Normal), aliquot TARGET-30-PASYTP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d755a20e-78ac-41bc-9df0-f3acb7982f7d

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.3636G>T p.E1212D | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55093470; called by muse, mutect2, varscan2
- TDRD6 | c.4565G>T p.R1522I | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV60175224, COSV60176365; called by muse, mutect2, varscan2
- TDRD6 | c.4566A>T p.R1522S | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV60176371; called by muse, mutect2, varscan2
- KLHL3 | c.1719G>T p.T573= | Silent (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- NPAP1 | c.75C>T p.P25= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs776835685, COSV61508007; called by muse, mutect2, varscan2
